Gene-level copy-number profile of tumor specimen HCM-BROD-0025-C16-01A from HCMI case HCM-BROD-0025-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 73.7 years (26,928 days).
Specimen HCM-BROD-0025-C16-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a88fc549-d92e-4623-8a2e-f49ddd01f975.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0025-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/bcfb674c-0b2a-4eb9-a082-56b6bb7ec6cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 603; copy number 1: 9,448; copy number 2: 46,796; copy number 3: 1,818; copy number 4: 218; copy number 5: 11; copy number 6: 5; copy number 7: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 94 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:10,394,489–10,629,307, 3 genes: MIR885, ATP2B2-IT1, ATP2B2-IT2.
- chr3:35,215,705–39,172,952, 75 genes (within-gene range 0–1) (broad region; genes not listed).
- chr3:50,558,025–50,596,168, 2 genes: C3orf18, HEMK1.
- chr3:52,777,595–52,792,068, 1 gene: ITIH1.
- chr4:3,889,356–3,902,594, 2 genes: OR7E163P, OR7E162P.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr20:14,933,843–15,280,873, 4 genes (within-gene range 0–1): AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.
- chr21:13,762,338–13,827,627, 6 genes: FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,412,264, 3 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2.
- chr15:21,053,004–21,152,970, 4 genes, copy number 6–10: AC037471.1, BCAR1P2, RN7SL400P, AC126335.2.
- chr20:47,478,214–47,493,085, 3 genes, copy number 5: RPL35AP, RNU6-497P, RNU6-563P.
- chr20:53,544,615–53,875,557, 7 genes, copy number 5: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1.
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 9,398. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
